HCMI case HCM-SANG-1300-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f5dccb7f-c0c5-4990-9092-6f0875a1fe04

Demographics
Sex at birth: male; Days to birth: -23,558 days (64.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lung, NOS; Uicc clinical stage: Stage IVA; Uicc pathologic n: N1; Uicc pathologic stage: Stage IVA; Uicc pathologic t: T4; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes; Vascular invasion type: Extramural.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.

Molecular and laboratory tests
- Test: Negative; Mismatch repair mutation: Yes.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample HCM-SANG-1300-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-1300-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-1300-C18-85A-01D-A80T-32, HCM-SANG-1300-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
